Somatic mutation profile of tumor specimen MP2PRT-PATLER-TMP1-A (aliquot MP2PRT-PATLER-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATLER, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,629 days).
Specimen MP2PRT-PATLER-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6377ffe4-e53f-4844-bca6-c8abdd4bb7c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATLER-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATLER-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfefb3f2-0bb6-414f-8673-13ef6f917de5

The open-access MAF lists 68 somatic variants for this specimen: 52 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 12, Intron 2, Nonsense Mutation 2, 3'Flank 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.3068G>A p.R1023Q | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs770362206, COSV60624306; called by muse, mutect2
- ADAMTS20 | c.3365G>T p.R1122L | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as rs752110033, COSV67131309; called by muse, mutect2, varscan2
- ADGRV1 | c.6368C>G p.S2123* | Nonsense Mutation (SNP) | VAF 14/200 reads (7%) | catalogued as COSV101316260; called by muse, mutect2
- ANO3 | c.171C>G p.F57L | Missense Mutation (SNP) | VAF 125/328 reads (38%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV99881919; called by muse, mutect2, varscan2
- ATP10D | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs775477328, COSV99906279; called by muse, mutect2
- CFAP91 | c.1302G>C p.K434N | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV56340524; called by muse, mutect2
- COL27A1 | c.4247G>A p.R1416Q | Missense Mutation (SNP) | VAF 171/442 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.14); catalogued as rs200663129, COSV61921184; called by muse, mutect2, varscan2
- COL5A2 | c.3881G>A p.R1294H | Missense Mutation (SNP) | VAF 102/285 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150063612; called by muse, mutect2, varscan2
- CYB5RL | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV55278475; called by muse, mutect2
- DDX50 | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.531); catalogued as COSV65292236; called by muse, mutect2, varscan2
- DNAJB9 | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV50812230; called by muse, mutect2, varscan2
- HOMEZ | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); catalogued as rs1453073811; called by muse, mutect2, varscan2
- KDM4C | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV99060170; called by muse, mutect2, varscan2
- KIF16B | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 148/413 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs751854805; called by muse, mutect2, varscan2
- KLHL15 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60139780; called by muse, mutect2
- LRTM1 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 63/729 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs79973856, COSV55593130; called by muse, mutect2
- MAGEC1 | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 154/393 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as COSV53569466, COSV53580714; called by muse, varscan2
- MAN1A1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV63782072; called by muse, mutect2, varscan2
- NSD1 | c.5932G>A p.E1978K | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV61771534; called by muse, mutect2, varscan2
- RYR3 | c.12471G>T p.K4157N (on ENST00000389232; = p.K4158N on NM_001036.6) | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as COSV66777175; called by muse, mutect2
- SETD2 | c.5389C>T p.Q1797* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV57431960; called by muse, varscan2
- SLC44A2 | c.2038G>A p.G680S | Missense Mutation (SNP) | VAF 97/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761484693; called by muse, mutect2, varscan2
- SNRPN | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 66/750 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs775190561, COSV57594364, COSV57599888; called by muse, mutect2
- ZFP69 | c.1040G>T p.R347I | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV65529184, COSV65529577; called by muse, mutect2, varscan2
- ADAMTS16 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 111/354 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCORL1 | c.3922G>T p.A1308S | Missense Mutation (SNP) | VAF 332/782 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- CBFA2T3 | c.1733C>G p.S578C | Missense Mutation (SNP) | VAF 32/836 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH18 | c.2137C>G p.Q713E | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.155); called by muse, mutect2
- CHST1 | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 255/595 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CORIN | c.2547G>C p.E849D | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- EGFLAM | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ELMO1 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- EPB41L5 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR156 | c.1967G>C p.R656T | Missense Mutation (SNP) | VAF 232/558 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- H2BC15 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); called by muse, mutect2
- IGHV1-69 | chr14:106714682 del TCTCTCGCAC | Missense Mutation (DEL) | VAF 14/30 reads (47%) | called by mutect2, pindel*, varscan2
- IGKV1D-16 | chr2:90100725 ATAATAGTTACCCTCCCAC>CCTCAGG | Missense Mutation (DEL) | VAF 64/203 reads (32%) | called by pindel, varscan2*
- MEI1 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2
- MMP10 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RBM47 | c.1587G>T p.Q529H (on ENST00000295971 / NM_001098634.2; = p.Q460H on NM_019027.4) | Missense Mutation (SNP) | VAF 17/379 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2
- RRP12 | c.3583C>G p.L1195V | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- SETD2 | c.5294C>T p.S1765F | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, varscan2
- SMC1B | c.1397_1401dup p.S468Qfs*12 | Frame Shift Ins (INS) | VAF 20/128 reads (16%) | called by mutect2, varscan2
- ST13 | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TKFC | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TMC1 | c.547T>C p.S183P | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- UBE2R2 | c.264G>C p.E88D | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- UGT1A4 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 21/409 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.175); called by muse, mutect2
- WDFY4 | c.9393G>C p.K3131N | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- WDR33 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 33/386 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- YBX1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 62/513 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZZZ3 | c.441G>C p.R147S | Missense Mutation (SNP) | VAF 10/287 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2
- B4GALT2 | c.493C>T p.L165= | Silent (SNP) | VAF 36/858 reads (4%) | called by muse, mutect2
- CD99L2 | c.147C>G p.T49= | Silent (SNP) | VAF 114/341 reads (33%) | called by muse, mutect2, varscan2
- FHOD3 | c.381C>A p.L127= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as COSV57170051; called by muse, mutect2, varscan2
- MLX | c.492C>T p.F164= | Silent (SNP) | VAF 85/391 reads (22%) | called by muse, mutect2, varscan2
- OR9Q2 | c.723C>T p.C241= | Silent (SNP) | VAF 47/549 reads (9%) | catalogued as rs149505103, COSV61112628; called by muse, mutect2
- PTH1R | c.951G>A p.E317= | Silent (SNP) | VAF 74/405 reads (18%) | catalogued as COSV57317281, COSV57318121; called by muse, mutect2, varscan2
- PTPN21 | c.2487C>T p.I829= | Silent (SNP) | VAF 85/500 reads (17%) | catalogued as rs1347113372; called by muse, mutect2, varscan2
- RSPH10B2 | c.232C>T p.L78= | Silent (SNP) | VAF 65/270 reads (24%) | called by muse, mutect2, varscan2
- SCN3A | c.4740C>G p.L1580= | Silent (SNP) | VAF 47/255 reads (18%) | catalogued as rs754806515, COSV51806089; called by muse, mutect2, varscan2
- SPOCK1 | c.831C>T p.Y277= | Silent (SNP) | VAF 52/281 reads (19%) | catalogued as rs138803538, COSV56457823; called by muse, mutect2, varscan2
- TSPEAR | c.1680C>T p.V560= | Silent (SNP) | VAF 46/472 reads (10%) | called by muse, mutect2
- TULP1 | c.1584C>T p.F528= | Silent (SNP) | VAF 24/888 reads (3%) | called by muse, mutect2
- IGKV1OR2-108 | chr2:113406873 del CAC | 3'Flank (DEL) | VAF 40/62 reads (65%) | called by mutect2, pindel, varscan2
- TCF7L2 | c.552+49304G>C | Intron (SNP) | VAF 160/403 reads (40%) | called by muse, mutect2, varscan2
- TRIM8 | c.*510C>T | 3'UTR (SNP) | VAF 309/798 reads (39%) | catalogued as rs1386357224; called by muse, mutect2, varscan2
- TTN | c.34265-5684G>A | Intron (SNP) | VAF 75/163 reads (46%) | called by muse, mutect2, varscan2
